Surgical pathology report (de-identified scan), TCGA case TCGA-CK-5916, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Harvard, specimen TCGA-CK-5916-01A (Primary Tumor).

DIAGNOSIS:

1) SPECIMEN LABELED "RIGHT COLON":

ADENOCARCINOMA (11.8 cm), poorly differentiated, with neuroendocrine and signet ring cell features and focal mucin production. Tumor extends through the muscularis propria and involves the visceral peritoneum. The proximal, distal, and radial resection margins are free of tumor. Lymphovascular invasion is present. Appendix with fibrous obliteration and peri-appendiceal adhesions. METASTATIC CARCINOMA in one of thirty two (1:32) lymph nodes.

CLINICAL DATA:

History: None given.

Operation: Rt colectomy

Clinical Diagnosis: Colon cancer

The specimen is received fresh, in the frozen section room, labeled with the patient's name, unit number, and "1) Rt colon (tumor bank)", and consists of a partial colectomy specimen consisting of terminal ileum (8 cm length, 3.1 cm diameter), colon (27 cm length, 4.5 cm diameter), appendix (4.5 cm length, 0.5 cm diameter), proximal stapled resection margin (4.1 cm), and distal stapled resection margin (4.6 cm). There is a red/tan, ulcerating, necrotic mass (11.8 x 5.5 x 5.0 cm) with raised, rolled borders at the ileocecal valve, extending through the wall creating a large, matted mass within the pericolonic fat, extending to and possibly involving the appendix. The mass is 8 cm from the proximal stapled resection margin, and 23 cm from the distal stapled resection margin. A tan mucosal polyp (0.4 x 0.3 x 0.2 cm) is present 5.5 cm distal to the aforementioned ileocecal valve mass, and comes to within 18 cm of the distal stapled resection margin, and 17 cm of the proximal stapled resection margin. The remaining colonic mucosa is tan/pink with normal folds. The ileomucosa is tan/pink and velvety, with focally flattened folds adjacent to the mass. Multiple tan/white, indurated to tan/pink, rubbery lymph nodes are identified, ranging from 0.5-1.5 cm in greatest dimension. Representative sections of the tumor and normal colon, as well as half of a lymph node are submitted to the tumor bank for special studies.

Micro 1: proximal stapled resection margin, en face, 2 frag,
Micro 2: distal stapled resection margin, en face, 2 frag,
Micro 3: appendix tip - bisected, and mid appendix, 3 frag,
Micro 4: appendiceal os in relation to cecal/ileocecal mass,
Micro 5-6: ileocecal valve mass, deepest extension, 2 frag,
Micro 7: mass in relation to right colon, 1 frag,
Micro 8: mass in relation to ileocecal valve and terminal ileum, 1 frag,
Micro 9: additional colon mucosal polyp, 2 frag,
Micro 10: remaining half of grossly positive lymph node (remainder to bank), 1 frag,
Micro 11: five single whole lymph nodes, 5 frag,
Micro 12: seven single whole lymph nodes, 7 frag,
Micro 13: eight single whole lymph nodes, 8 frag,
Micro 14: six single whole lymph nodes, 6 frag,
Micro 15: five single whole lymph nodes, 5 frag,

SPECIMEN TYPE: COLON, SEGMENTAL RESECT FOR TUMOR

Source: NCI Genomic Data Commons file 13f4779b-5a6c-46fd-9848-4ea56e12743c (TCGA-CK-5916.2F0D2DB5-DBF1-49E6-87D4-EB91C938536C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).